Surgical pathology report (de-identified scan), TCGA case TCGA-UZ-A9PM, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site University of California San Francisco, specimen TCGA-UZ-A9PM-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Patient Name: [REDACTED]
Med. Rec. #: [REDACTED] Visit #: [REDACTED]
DOB: [REDACTED] Male
Soc. Sec. #: [REDACTED] Location: [REDACTED]
Physician(s): [REDACTED]

Accession #: [REDACTED]
Service Date: [REDACTED]
Received: [REDACTED]
Client: [REDACTED]

FINAL PATHOLOGIC DIAGNOSIS

- A. Left Kidney, laparoscopic nephrectomy:
1. Papillary renal cell carcinoma, type 1, Fuhrman grade 2, 10cm in greatest dimension, margins free of tumor; see comment.
2. Ureter with no tumor identified.
3. Adrenal gland with no tumor identified.
- B. Perirenal fat, laparoscopic nephrectomy: Adipose tissue, no tumor identified.

COMMENT:

This papillary renal cell carcinoma, Fuhrman grade 2, predominantly type 1, shows large areas of necrosis (~40% of the tumor mass). Histologically the tumor is comprised of papillae with fibrovascular cores filled with abundant foamy histiocytes (strongly CD68 positive). The papillae are lined by a single layer of low cuboidal to columnar cells with relatively abundant cytoplasm and moderately enlarged nuclei with easily discernable nucleoli, consistent with Fuhrman grade 2. Strikingly, the tumor cells and foamy histiocytes show extensive granular cytoplasmic pigment, consistent with hemosiderin. There is a minor component of solid/tubular architecture that is comprised of larger cells with granular eosinophilic cytoplasm and large nuclei with prominent nucleoli. Given the marked hemosiderin pigment immunohistochemical stains for cytokeratin and CD68 were necessarily performed to confirm the diagnosis. The cytokeratin strongly stained the malignant cells while the CD68 highlighted the foamy histiocytes.

Kidney Tumor Synoptic Comment

- Histologic type: Papillary renal cell carcinoma (chromophil), type 1.
- Grade: Fuhrman grade 2.
- Maximum tumor diameter: 10 cm.
- Site within kidney: Posterior mid kidney.
- Renal pelvis: Normal.
- Ureter: Normal.
- Renal sinus: Normal, no tumor.
- Hilar renal veins: Normal, no tumor.
- Intrarenal veins and lymphatics: Normal, no tumor.

ICD-8-3
Carcinoma, papillary
renal cell 8260/3
Site: @ Kidney NOS C64.9
9/23/2014

[page 2 of 2]
-Adrenal gland: Normal.
-Capsule/perirenal fat: Tumor does not penetrate capsule.
-Hilar lymph nodes (number positive/number of nodes): 0/0.
-Resection margins: Negative.
-Proximity to nearest margin: 0.3 cm.
-Stage: pT2N0MX.
-Additional comments: See above. [redacted] has reviewed the case and concurs with the diagnosis.

Specimen(s) Received

A: Left kidney
B: Peri-renal fat

Clinical History

The patient is a [redacted]-year-old male with left kidney cancer, who undergoes left laparoscopic radical nephrectomy.

Gross Description

The specimen is received in formalin in two parts, each labeled with the patient's name and medical record number.

Part A is not additionally labeled. It consists of a morcellated, single kidney and associated perinephric fat weighing 1280 gm. The kidney itself measures 15.0 x 12.0 x 8.0 cm. The external surface of the perinephric fat, as well as exposed renal surface, is inked with black ink, and the specimen is bisected, revealing a single, oval tumor measuring 10.0 x 6.0 cm. The interior of the tumor is composed of grumous red-brown and yellow-orange material. The tumor appears to be entirely encapsulated within the substance of the kidney. The tumor is located primarily posteriorly within the kidney, and distorts, but does not involve the renal pelvis or vascular pedicle. Additionally identified is a single adrenal gland measuring 5.0 x 2.0 x 0.3 cm. The superior pole of the kidney appears to be avulsed, exposing the renal pelvis. The area of avulsion does not grossly involve tumor. Representative sections are submitted as follows:

Cassette A1: Vascular and ureteral margins.
Cassette A2: Area of avulsion, closest approach to tumor.
Cassettes A3-A4: Tumor, relation to renal pelvis.
Cassette A5: Tumor, relation to capsule.
Cassette A6: Uninvolved kidney.
Cassette A7: Adrenal gland.
Cassette A8: Candidate lymph nodes.

Part B is additionally labeled "peri-renal fat L." It consists of multiple fragments of fat, measuring 12.0 x 5.5 x 1.5 cm in aggregate. Excess fat is removed, and tan-red areas from within the fat are submitted in cassettes B1 through B3.

The immunoperoxidase stain(s) reported above were developed and their performance characteristics determined by the [redacted]. They have not been cleared or approved by the U. S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 ("CLIA") as qualified to perform high-complexity clinical testing.

Diagnosis based on gross and microscopic examinations. Final diagnosis made by attending pathologist following review of all pathology slides.

[redacted] /Pathology Resident

[redacted] /Pathologist
Electronically signed out on [redacted]

Criteria	hw 1/6/14	Yes	No

Source: NCI Genomic Data Commons file 028bd610-f769-4d7f-9136-c4a1ffe7bfc3 (TCGA-UZ-A9PM.B2F5409B-F6C8-423A-8399-2DAFD2F63140.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).